Gene-level copy-number profile of tumor specimen ALCH-B2VV-TTP1-A from ALCHEMIST case ALCH-B2VV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.7 years (26,195 days).
Specimen ALCH-B2VV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00d217d0-603a-453a-943a-6048d70a15a7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2VV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/af4b57bb-1b04-4f87-aa9f-88cb503a52cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 3,565; copy number 2: 55,118; copy number 3: 134; copy number 4: 18; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–2): AL512383.1.
- chr1:225,700,264–225,752,258, 3 genes: AC099066.2, AC099066.1, RNU6-1304P.
- chr2:232,368,576–232,368,697, 1 gene: AC068134.3.
- chr7:63,632,608–63,636,617, 1 gene: AC006015.1.
- chr7:99,416,739–99,466,197, 5 genes (within-gene range 0–1): PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr11:134,032,216–134,067,936, 2 genes (within-gene range 0–2): LINC02731, AP000911.1.
- chr15:25,176,832–25,249,279, 40 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43.
- chr16:89,906,157–89,972,832, 7 genes (within-gene range 0–2): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1.
- chr17:16,438,767–16,492,193, 6 genes (within-gene range 0–2): SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:21,238,870–21,253,410, 1 gene: NATD1.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:76,799,044–76,807,102, 1 gene: LINC02080.
- chr19:1,241,746–1,244,825, 1 gene: ATP5F1D.
- chr22:43,038,585–43,089,419, 2 genes: TTLL1-AS1, TTLL1.
- chr22:43,151,547–43,163,242, 1 gene: TSPO.
- chr22:44,569,295–44,572,453, 1 gene: LINC00207.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:1,275,530–1,279,244, 1 gene, copy number 12: FAM174C.

Autosomal genes at a single copy (total copy number 1): 741. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
